Somatic mutation profile of tumor specimen MP2PRT-PASLXT-TBP1-A (aliquot MP2PRT-PASLXT-TBP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PASLXT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,196 days).
Specimen MP2PRT-PASLXT-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f7b1fef-a6ef-473b-b0d6-ba651dcaa204.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASLXT-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASLXT-NB1-B-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ee95b9f-4f24-4984-b7dd-40652f244037

The open-access MAF lists 19 somatic variants for this specimen: 19 protein-altering or splice-affecting.
By variant classification: Missense Mutation 16, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ETV6 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 80/528 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1511682, COSV56765384, COSV56765583; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 56/432 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- C12orf54 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 89/428 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.675); catalogued as COSV58359888; called by muse, mutect2, varscan2
- CADM3 | c.427C>T p.R143W (on ENST00000368125 / NM_001127173.3; = p.R177W on NM_021189.5) | Missense Mutation (SNP) | VAF 105/430 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs1021719284, COSV100930343; called by muse, mutect2, varscan2
- CHIC1 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 32/117 reads (27%) | catalogued as rs1441258979; called by muse, mutect2, varscan2
- DENND2C | c.2243C>T p.S748F (on ENST00000393274 / NM_001256404.2; = p.S691F on NM_198459.4) | Missense Mutation (SNP) | VAF 74/327 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV67924700; called by muse, mutect2, varscan2
- ENPP6 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 108/596 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.238); catalogued as rs765721760, COSV57071201; called by muse, mutect2, varscan2
- RNF40 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 109/520 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs770060642; called by muse, mutect2, varscan2
- SCN1A | c.4888G>A p.V1630M (on ENST00000303395 / NM_001202435.3; = p.V1619M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/379 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs121917914, CM076499, CM1211403, COSV57691279; ClinVar: not provided; called by muse, mutect2, varscan2
- SEMA4F | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 107/387 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs200489586; called by muse, mutect2, varscan2
- ATF5 | c.504C>A p.N168K | Missense Mutation (SNP) | VAF 116/550 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDH7 | c.1917T>G p.I639M | Missense Mutation (SNP) | VAF 75/429 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- DTX3L | c.622_623del p.R208Efs*16 | Frame Shift Del (DEL) | VAF 97/472 reads (21%) | called by pindel, varscan2
- HCFC2 | c.2051T>A p.V684D | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KMT2D | c.8757_8758insACCA p.G2920Tfs*23 | Frame Shift Ins (INS) | VAF 78/663 reads (12%) | called by pindel, varscan2
- OBSL1 | c.2409T>A p.D803E | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.147); called by muse, mutect2
- PCDHGA1 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 125/499 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PTPRK | c.2441A>G p.E814G (on ENST00000368215 / NM_001291984.2; = p.E815G on NM_002844.4) | Missense Mutation (SNP) | VAF 48/444 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.156); called by mutect2, varscan2
- SLC8A3 | c.1071A>C p.Q357H | Missense Mutation (SNP) | VAF 126/779 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
